Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3662, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3662-01A (Primary Tumor).

Diagnosis/ diagnoses:

Resected colon sample (10 cm in length) with an ulcerated, moderately differentiated adenocarcinoma of the colorectal type, measuring a max of 3 cm in diameter, with widespread infiltration of the pericolic fatty tissue, circumscribed penetration of the overlying serosa, and four regional lymph node metastases. Tumor-free colon resection margins. In addition, two tubular adenomas with moderate dysplasia (synonym: low-grade intraepithelial neoplasia).

Tumor stage: pT4 pN2 (4/15) pM1 (clinically liver metastases); G2, L0, V0, locally R0.

Source: NCI Genomic Data Commons file 98f9702b-3e0c-41c7-8f32-287245efb5c7 (TCGA-AA-3662.59A86F24-7500-467B-9E3F-9CBF5F872AF7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).